CGCI case HTMCP-03-06-02340 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f07f2302-2276-4d5c-b52b-0b900464d39c

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 48 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 48.5 years (17,732 days); Year of diagnosis: 2016; Method of diagnosis: Biopsy; AJCC clinical T: T1b2; AJCC clinical N: N0; AJCC clinical M: M0; FIGO stage: Stage IB2; FIGO staging edition year: 2009; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 195 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 33 days; Days to treatment end: 47 days.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 2400; Treatment anatomic sites: Cervix.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 195 days; Disease response: With Tumor.

Molecular and laboratory tests
- CDKN2A (IHC): Positive.

Other clinical attributes
- Day 0: Pregnancy outcome: Miscarriage.
- Day 0: Nadir CD4 count: 15.
- Day 0: Pregnancy outcome: Induced Abortion.
- Day 0: Weight: 69 kg; Height: 170 cm; BMI: 23.9; CD4 count: 563; Haart treatment indicator: Yes; HIV viral load: 3021; Hormonal contraceptive use: Never Used; Hysterectomy type: Not Performed; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Comorbidities: HIV/AIDS.
- Risk factors: HIV/AIDS.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02340-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02340-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02340-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); Weight kg at diagnosis: 69 kg; History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 05; Pregnancies count miscarriage: 01; Pregnancies count induced abortion: 03; Pregnancies count ectopic: 00; Pregnancies count stillbirth: 00; Total pregnancy count: 09; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Squamous Cell Carcinoma, Keratinizing; Keratinization squamous cell: Keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Year of HIV diagnosis: 2003; Nadir cd4 counts: 0015; HIV rna load at diagnosis: 003021; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes; Cd4 counts at diagnosis: 0563.
- Follow-up form, Treatment, Radiation therapy info: Brachytherapy type: HDR.
- Treatments, Treatment: Therapy regimen: Initial; Treatment type: Radiation Therapy; Radiation therapy end: Yes.
